Somatic mutation profile of tumor specimen MP2PRT-PASFYG-TMP1-A (aliquot MP2PRT-PASFYG-TMP1-A-1-0-D-A81X-36) from MP2PRT case MP2PRT-PASFYG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.4 years (3,077 days).
Specimen MP2PRT-PASFYG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b78a58ef-00b8-4b13-aeee-cb0806f23f5a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASFYG-NB1-B (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASFYG-NB1-B-1-0-D-A81X-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/91a7442f-4607-44e2-82b9-2c92e46078cc

The open-access MAF lists 88 somatic variants for this specimen: 56 protein-altering or splice-affecting, 27 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 27, Nonsense Mutation 5, 5'Flank 1, 3'Flank 1, 5'UTR 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK | c.7576G>A p.E2526K | Missense Mutation (SNP) | VAF 54/490 reads (11%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.969); catalogued as rs750483775, COSV57202331; called by muse, mutect2, varscan2
- AHNAK | c.6910G>C p.E2304Q | Missense Mutation (SNP) | VAF 46/480 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.327); catalogued as COSV99949232; called by muse, mutect2
- BCAR3 | c.2005C>G p.L669V | Missense Mutation (SNP) | VAF 14/374 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99550083; called by muse, mutect2
- CDIPT | c.343C>T p.R115* | Nonsense Mutation (SNP) | VAF 92/321 reads (29%) | catalogued as rs772790263, COSV54888594; called by muse, mutect2, varscan2
- CORO1A | c.726G>A p.M242I | Missense Mutation (SNP) | VAF 66/862 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.194); catalogued as rs1219658734; called by muse, mutect2
- ELOF1 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 38/390 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.221); catalogued as rs1314367685; called by muse, mutect2
- FRAS1 | c.3499C>T p.R1167C | Missense Mutation (SNP) | VAF 24/418 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs373504897; called by muse, mutect2
- GRIN2B | c.3499G>A p.V1167I | Missense Mutation (SNP) | VAF 134/519 reads (26%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs1042339; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KRT10 | c.428C>G p.S143C | Missense Mutation (SNP) | VAF 64/694 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs563178579, COSV99510042; called by muse, mutect2
- MYBPH | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 33/674 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs145262459, COSV99703959; called by muse, mutect2
- NCAPH | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 126/438 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.517); catalogued as COSV53637827; called by muse, mutect2, varscan2
- NEDD4 | c.125C>T p.S42L | Missense Mutation (SNP) | VAF 30/410 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.01); catalogued as COSV100164202; called by muse, mutect2
- OLFML2B | c.335C>T p.S112L | Missense Mutation (SNP) | VAF 32/594 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as rs919118727, COSV99668643; called by muse, mutect2
- OR52K1 | c.28C>T p.H10Y | Missense Mutation (SNP) | VAF 86/256 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV56903124; called by muse, mutect2, varscan2
- OTOGL | c.3790G>A p.E1264K (on ENST00000547103; = p.E1255K on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/183 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.204); catalogued as COSV72006810; called by muse, mutect2
- PCDHGA4 | c.1832G>A p.R611H | Missense Mutation (SNP) | VAF 21/346 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.123); catalogued as rs1355845145; called by muse, mutect2
- PTGER3 | c.932C>T p.S311L | Missense Mutation (SNP) | VAF 97/312 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as rs1295766665; called by muse, mutect2, varscan2
- RSL1D1 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 38/472 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); catalogued as rs766024466; called by muse, mutect2
- SCUBE1 | c.1229G>A p.R410H | Missense Mutation (SNP) | VAF 35/388 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.206); catalogued as rs563690047, COSV62611479; called by muse, mutect2
- SMG7 | c.3338C>T p.S1113F | Missense Mutation (SNP) | VAF 36/323 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.154); catalogued as COSV61632067; called by muse, mutect2, varscan2
- SPPL2A | c.919C>T p.R307* | Nonsense Mutation (SNP) | VAF 59/229 reads (26%) | catalogued as rs1407126115; called by muse, mutect2, varscan2
- TCHH | c.5158G>A p.E1720K | Missense Mutation (SNP) | VAF 118/349 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.146); catalogued as COSV64273805; called by muse, mutect2, varscan2
- TENM2 | c.4911G>C p.K1637N (on ENST00000518659 / NM_001122679.2; = p.K1398N on NM_001080428.3) | Missense Mutation (SNP) | VAF 25/539 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.434); catalogued as COSV69128968; called by muse, mutect2
- XKR8 | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 26/542 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as COSV65835498; called by muse, mutect2
- ZNF711 | c.1079G>A p.R360K | Missense Mutation (SNP) | VAF 20/244 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs756129967; called by muse, mutect2
- ABCC1 | c.1109T>A p.L370Q | Missense Mutation (SNP) | VAF 245/662 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACAD9 | c.1819G>C p.E607Q | Missense Mutation (SNP) | VAF 111/361 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- AHNAK | c.5941G>C p.E1981Q | Missense Mutation (SNP) | VAF 60/612 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- APC | c.2754G>C p.E918D | Missense Mutation (SNP) | VAF 38/494 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2
- ATXN7L1 | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 48/568 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.03); called by muse, mutect2
- BTBD9 | c.820G>C p.E274Q | Missense Mutation (SNP) | VAF 55/215 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- CDH10 | c.1992G>C p.E664D | Missense Mutation (SNP) | VAF 70/249 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRAMP1 | c.3127G>A p.E1043K | Missense Mutation (SNP) | VAF 26/388 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.941); called by muse, mutect2
- DENND5A | c.1721G>C p.R574T | Missense Mutation (SNP) | VAF 77/246 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- DUSP6 | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 23/838 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.079); called by muse, mutect2
- FIBP | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 24/506 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.359); called by muse, mutect2
- FIGN | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 18/440 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.048); called by muse, mutect2
- H3C2 | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 34/496 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.835); called by muse, mutect2
- IGHV3-43 | chr14:106470262 GTATC>TCCAG | Missense Mutation (ONP) | VAF 17/124 reads (14%) | called by pindel, varscan2*
- INHBB | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 74/706 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LONRF2 | c.2068C>G p.Q690E | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NAIF1 | c.541G>C p.E181Q | Missense Mutation (SNP) | VAF 28/509 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2
- OGDH | c.679G>C p.D227H | Missense Mutation (SNP) | VAF 26/444 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2
- OR8S1 | c.360T>G p.Y120* | Nonsense Mutation (SNP) | VAF 22/504 reads (4%) | called by muse, mutect2
- PPP4C | c.595G>T p.D199Y | Missense Mutation (SNP) | VAF 27/410 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- RERE | c.1608C>A p.F536L | Missense Mutation (SNP) | VAF 42/381 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- RLF | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 59/640 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- STK39 | c.1042G>T p.E348* | Nonsense Mutation (SNP) | VAF 24/373 reads (6%) | called by muse, mutect2
- SYMPK | c.897G>C p.K299N | Missense Mutation (SNP) | VAF 54/441 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UGGT2 | c.4015A>G p.R1339G | Missense Mutation (SNP) | VAF 56/178 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP34 | c.1948C>G p.Q650E | Missense Mutation (SNP) | VAF 25/493 reads (5%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.011); called by muse, mutect2
- VSTM2A | c.472C>T p.Q158* | Nonsense Mutation (SNP) | VAF 161/495 reads (33%) | called by muse, mutect2, varscan2
- ZBED9 | c.1307C>G p.S436C | Missense Mutation (SNP) | VAF 38/456 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- ZC3H12C | c.989G>C p.R330T | Missense Mutation (SNP) | VAF 108/358 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- ZCCHC7 | c.894C>G p.F298L | Missense Mutation (SNP) | VAF 32/420 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.034); called by muse, mutect2
- ZNF224 | c.280A>G p.T94A | Missense Mutation (SNP) | VAF 93/353 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADGRB3 | c.690G>C p.L230= | Silent (SNP) | VAF 143/460 reads (31%) | called by muse, mutect2, varscan2
- BAG6 | c.1329G>A p.Q443= | Silent (SNP) | VAF 64/790 reads (8%) | catalogued as COSV52987887; called by muse, mutect2
- CACNG4 | c.27G>A p.Q9= | Silent (SNP) | VAF 53/549 reads (10%) | called by muse, mutect2, varscan2
- CCDC168 | c.11191C>T p.L3731= | Silent (SNP) | VAF 85/250 reads (34%) | catalogued as rs1394334020; called by muse, mutect2, varscan2
- CEP350 | c.9312G>C p.L3104= | Silent (SNP) | VAF 19/324 reads (6%) | called by muse, mutect2
- DERL3 | c.129C>T p.F43= | Silent (SNP) | VAF 194/766 reads (25%) | catalogued as COSV51956831; called by muse, mutect2, varscan2
- EP400 | c.4827C>T p.L1609= | Silent (SNP) | VAF 38/407 reads (9%) | catalogued as rs774631468; called by muse, mutect2
- FAM83H | c.1494G>A p.P498= | Silent (SNP) | VAF 58/971 reads (6%) | catalogued as rs1554623027; called by muse, mutect2
- GNAL | c.78G>A p.P26= | Silent (SNP) | VAF 44/856 reads (5%) | called by muse, mutect2
- HTT | c.381C>T p.I127= | Silent (SNP) | VAF 74/245 reads (30%) | catalogued as rs1419687761; called by muse, mutect2, varscan2
- INHBB | c.438C>T p.F146= | Silent (SNP) | VAF 162/465 reads (35%) | catalogued as rs1484887598, COSV54678476; called by muse, mutect2, varscan2
- IRS4 | c.120G>A p.P40= | Silent (SNP) | VAF 195/432 reads (45%) | catalogued as rs1405858973, COSV64533341; called by muse, mutect2, varscan2
- KCNT1 | c.2127G>C p.L709= (on ENST00000488444; = p.L728= on NM_020822.3) | Silent (SNP) | VAF 31/665 reads (5%) | catalogued as rs1057522862; ClinVar: likely benign; called by muse, mutect2
- KIAA2026 | c.774G>C p.L258= | Silent (SNP) | VAF 25/178 reads (14%) | called by muse, mutect2, varscan2
- KIF26B | c.5730C>T p.S1910= | Silent (SNP) | VAF 80/902 reads (9%) | called by muse, mutect2
- NEB | c.7950G>A p.Q2650= | Silent (SNP) | VAF 14/397 reads (4%) | called by muse, mutect2
- OR10H1 | c.237G>A p.P79= | Silent (SNP) | VAF 185/412 reads (45%) | catalogued as rs1318938738, COSV58472317, COSV58472669; called by muse, mutect2, varscan2
- OR2A14 | c.186C>T p.L62= | Silent (SNP) | VAF 74/360 reads (21%) | called by muse, mutect2, varscan2
- PCDHB10 | c.1266C>T p.T422= | Silent (SNP) | VAF 43/533 reads (8%) | catalogued as rs782561316; called by muse, mutect2
- PDIA4 | c.402G>C p.V134= | Silent (SNP) | VAF 24/562 reads (4%) | called by muse, mutect2
- PDZRN3 | c.1941C>T p.R647= | Silent (SNP) | VAF 168/510 reads (33%) | catalogued as rs558539857, COSV55201786; called by muse, mutect2, varscan2
- PLCE1 | c.3706C>T p.L1236= | Silent (SNP) | VAF 88/335 reads (26%) | called by muse, mutect2, varscan2
- RAPH1 | c.2136C>T p.P712= | Silent (SNP) | VAF 31/287 reads (11%) | catalogued as rs1446574846; called by muse, mutect2, varscan2
- RIMBP3 | c.3108G>A p.A1036= | Silent (SNP) | VAF 58/1407 reads (4%) | catalogued as rs748806383; called by muse, mutect2
- SPOCD1 | c.3417C>T p.F1139= | Silent (SNP) | VAF 49/654 reads (7%) | called by muse, mutect2
- XKR8 | c.672C>G p.L224= | Silent (SNP) | VAF 23/489 reads (5%) | catalogued as COSV65834831; called by muse, mutect2
- XRCC5 | c.1860C>T p.I620= | Silent (SNP) | VAF 86/252 reads (34%) | catalogued as rs143457870; called by muse, mutect2, varscan2
- ADAM10 | c.-74C>T | 5'UTR (SNP) | VAF 72/867 reads (8%) | called by muse, mutect2
- G3BP1 | chr5:151770456 C>T | 5'Flank (SNP) | VAF 39/691 reads (6%) | called by muse, mutect2
- IGHV1-45 | chr14:106506995 ins A | 3'Flank (INS) | VAF 61/112 reads (54%) | called by mutect2, pindel*, varscan2
- PSG3 | c.*62C>T | 3'UTR (SNP) | VAF 10/166 reads (6%) | catalogued as COSV100548952; called by muse, mutect2
- SIGLEC6 | c.707-26G>A | Intron (SNP) | VAF 25/396 reads (6%) | called by muse, mutect2
